Somatic mutation profile of tumor specimen MMRF_2089_3_BM_CD138pos (aliquot MMRF_2089_3_BM_CD138pos_T2_KHS5U_L14849) from MMRF case MMRF_2089, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,417 days).
Specimen MMRF_2089_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 51e57899-fc73-499a-8f90-c4b43bba1098.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2089_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2089_1_PB_WBC_C3_KHS5U_L08822; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/920b5a76-cfee-4e0d-89fc-551fe3b97988

The open-access MAF lists 485 somatic variants for this specimen: 191 protein-altering or splice-affecting, 63 silent, 231 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 160, 3'UTR 129, Silent 63, Intron 63, 5'UTR 17, Nonsense Mutation 15, RNA 11, Frame Shift Del 9, 5'Flank 5, 3'Flank 5, Frame Shift Ins 2, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 52/113 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 53/96 reads (55%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs764146326, CD137626, CM076566, CM153816, COSV52671054, COSV52674651, COSV52678614; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ACAN | c.6701T>A p.L2234Q | Missense Mutation (SNP) | VAF 142/234 reads (61%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.977); catalogued as COSV100718699; called by muse, mutect2, varscan2
- ADGRD1 | c.1079A>G p.H360R | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as rs746975895; called by muse, mutect2, varscan2
- AMOTL1 | c.963G>A p.M321I | Missense Mutation (SNP) | VAF 80/270 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100133830; called by muse, mutect2, varscan2
- ANKRD42 | c.1030T>C p.F344L | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.883); catalogued as COSV52614252; called by muse, mutect2
- APOA2 | c.277C>T p.L93F | Missense Mutation (SNP) | VAF 72/260 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1215900467; called by muse, mutect2, varscan2
- BTG1 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 56/122 reads (46%) | catalogued as COSV55458809; called by muse, varscan2
- C1orf94 | c.1199G>T p.G400V (on ENST00000488417 / NM_001134734.2; = p.G210V on NM_032884.5) | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100974946; called by muse, mutect2, varscan2
- C3orf62 | c.259G>C p.E87Q | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV55539998; called by muse, mutect2, varscan2
- CARD6 | c.1780C>A p.Q594K | Missense Mutation (SNP) | VAF 16/387 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV54567172; called by muse, mutect2
- CAT | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 68/222 reads (31%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs749536831; called by muse, mutect2, varscan2
- CDH7 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.606); catalogued as COSV59883694; called by muse, mutect2, varscan2
- CEMIP | c.1026A>C p.K342N | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.651); catalogued as COSV54996611; called by muse, mutect2
- COL27A1 | c.2512G>A p.G838S | Missense Mutation (SNP) | VAF 124/216 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV61926137; called by muse, varscan2
- CUZD1 | c.454C>G p.P152A | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT tolerated (0.27); PolyPhen benign (0.053); catalogued as rs558554477; called by muse, mutect2, varscan2
- DFFA | c.526dup p.Q176Pfs*5 | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | catalogued as rs755703182; called by mutect2, pindel, varscan2
- DNAH5 | c.6661G>C p.E2221Q | Missense Mutation (SNP) | VAF 47/193 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.317); catalogued as COSV54235819; called by muse, mutect2, varscan2
- DYNC2H1 | c.6153G>C p.W2051C | Missense Mutation (SNP) | VAF 58/197 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100520050; called by muse, mutect2, varscan2
- FLG | c.2561G>T p.G854V | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs373305550; called by muse, varscan2
- GMPR | c.179C>T p.T60M | Missense Mutation (SNP) | VAF 42/214 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1162015376; called by muse, mutect2, varscan2
- HTR1F | c.834G>A p.W278* | Nonsense Mutation (SNP) | VAF 13/274 reads (5%) | catalogued as COSV60389673; called by muse, mutect2
- IGHV2-70 | c.314A>C p.N105T | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.072); catalogued as rs372581706; called by muse, varscan2
- IGHV2-70 | c.310A>T p.T104S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as rs368647772; called by muse, varscan2
- IGLV3-1 | c.97C>G p.P33A | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.166); catalogued as rs573884769; called by muse, mutect2, varscan2
- LY6E | c.140A>G p.Y47C | Missense Mutation (SNP) | VAF 18/634 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755330468; called by muse, mutect2
- MAGEL2 | c.3559C>T p.R1187* | Nonsense Mutation (SNP) | VAF 131/202 reads (65%) | catalogued as rs368965952, COSV100045884, COSV100046025; called by muse, mutect2, varscan2
- MAP1A | c.2592G>C p.K864N | Missense Mutation (SNP) | VAF 49/242 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100288595; called by muse, mutect2, varscan2
- MATN2 | c.799G>A p.G267S | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266765851; called by muse, mutect2
- MORC1 | c.19G>A p.A7T | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs375068069; called by muse, mutect2
- MUC12 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.06); catalogued as rs1256983713; called by muse, mutect2, varscan2
- MYCBP2 | c.12823G>A p.D4275N (on ENST00000357337; = p.D4313N on NM_015057.5) | Missense Mutation (SNP) | VAF 156/157 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62044146; called by muse, mutect2, varscan2
- NUP214 | c.3295C>T p.R1099W | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303316975; called by muse, mutect2, varscan2
- OR5H2 | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV62351327; called by muse, mutect2
- PARP14 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as rs564004211; called by muse, mutect2, varscan2
- PDCD11 | c.4291G>C p.G1431R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV63932868; called by muse, mutect2, varscan2
- PLXNA4 | c.4933C>A p.L1645M | Missense Mutation (SNP) | VAF 7/158 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.734); catalogued as COSV100322534; called by muse, mutect2
- PLXNB1 | c.3817C>T p.R1273C | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs777440373, COSV56486750; called by muse, mutect2
- PPP1R3C | c.60G>A p.M20I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs765370918; called by muse, mutect2, varscan2
- PTPRC | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.11); catalogued as rs762391496, COSV100723348; called by muse, mutect2, varscan2
- RAB10 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.063); catalogued as rs149788536; called by muse, mutect2
- RINL | c.1499T>C p.F500S (on ENST00000591812 / NM_001195833.2; = p.F386S on NM_198445.4) | Missense Mutation (SNP) | VAF 65/80 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758854340; called by muse, varscan2
- RYR3 | c.4118A>T p.D1373V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs755136349; called by muse, mutect2
- SALL1 | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV51760501; called by muse, mutect2, varscan2
- SLC1A5 | c.173C>T p.T58I | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs778524513; called by muse, mutect2, varscan2
- SNTG2 | c.1606A>G p.M536V | Missense Mutation (SNP) | VAF 72/127 reads (57%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs371161023; called by muse, mutect2, varscan2
- SORL1 | c.2224G>A p.E742K | Missense Mutation (SNP) | VAF 18/169 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.906); catalogued as COSV52759638; called by muse, mutect2, varscan2
- SPRR1A | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 34/608 reads (6%) | catalogued as COSV100201027; called by muse, mutect2
- SVOPL | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.69); catalogued as rs139868586; called by muse, mutect2, varscan2
- TRABD | c.672C>T p.S224= | Splice Region (SNP) | VAF 60/112 reads (54%) | catalogued as rs763947053; called by muse, mutect2, varscan2
- TRRAP | c.5867C>T p.T1956I (on ENST00000359863 / NM_001244580.1; = p.T1938I on NM_003496.3) | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.067); catalogued as rs782485850; called by muse, mutect2, varscan2
- UEVLD | c.305A>G p.H102R | Missense Mutation (SNP) | VAF 79/233 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1308377012; called by muse, mutect2, varscan2
- WNK3 | c.3440C>T p.S1147F | Missense Mutation (SNP) | VAF 80/80 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63614176; called by muse, mutect2, varscan2
- ZNF527 | c.789A>T p.Q263H | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV62229722; called by muse, mutect2
- ZNF679 | c.1210G>T p.G404* | Nonsense Mutation (SNP) | VAF 73/155 reads (47%) | catalogued as COSV55378362; called by muse, mutect2, varscan2
- ZNF679 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 73/157 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99738433; called by muse, mutect2, varscan2
- ZNF7 | c.851G>A p.G284E | Missense Mutation (SNP) | VAF 232/233 reads (100%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs1319987786; called by muse, mutect2, varscan2
- A2ML1 | c.1144G>C p.G382R | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ABCA4 | c.4783A>T p.T1595S | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACSM2B | c.383G>T p.R128L | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFF2 | c.2105A>T p.K702M | Missense Mutation (SNP) | VAF 72/73 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- AGFG2 | c.633G>C p.Q211H | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ALDH1L2 | c.899T>C p.L300P | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- ALLC | c.55T>C p.F19L | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- AMBRA1 | c.3525G>T p.M1175I (on ENST00000458649 / NM_001367468.1; = p.M1085I on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/161 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- ANKRD17 | c.4779C>G p.Y1593* | Nonsense Mutation (SNP) | VAF 75/137 reads (55%) | called by muse, mutect2, varscan2
- APH1A | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 33/192 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ARHGAP11A | c.766G>C p.D256H | Missense Mutation (SNP) | VAF 113/708 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- B4GALT6 | c.354C>A p.F118L | Missense Mutation (SNP) | VAF 126/172 reads (73%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARD6 | c.2896C>A p.Q966K | Missense Mutation (SNP) | VAF 28/389 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2
- CATSPERG | c.1839G>A p.M613I | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- CD207 | c.122C>G p.T41R | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CHD1 | c.669A>T p.E223D | Missense Mutation (SNP) | VAF 54/104 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLK3 | c.1750C>T p.L584F (on ENST00000395066 / NM_001130028.1; = p.L436F on NM_003992.4) | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- CMYA5 | c.9854A>T p.K3285M | Missense Mutation (SNP) | VAF 78/165 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- COL18A1 | c.2493+2T>G p.X831_splice (on ENST00000359759 / NM_130444.3; = p.X596_splice on NM_030582.4) | Splice Site (SNP) | VAF 58/174 reads (33%) | called by muse, mutect2, varscan2
- CPA4 | c.1155T>A p.D385E | Missense Mutation (SNP) | VAF 19/212 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); called by muse, mutect2
- CTNNA2 | c.1286T>A p.V429E | Missense Mutation (SNP) | VAF 58/186 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); called by muse, varscan2
- CTSK | c.189G>T p.E63D | Missense Mutation (SNP) | VAF 48/253 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- CTSV | c.113G>A p.R38K | Missense Mutation (SNP) | VAF 111/364 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DLGAP2 | c.2767C>G p.Q923E | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- DNAH9 | c.721T>G p.L241V | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.082); called by mutect2, varscan2
- DNAH9 | c.7916A>T p.N2639I | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.148); called by muse, mutect2
- DNAJC13 | c.1188_1190del p.F396_S397delinsL | In Frame Del (DEL) | VAF 55/144 reads (38%) | called by mutect2, pindel, varscan2
- DPP3 | c.1360G>C p.G454R | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DPYSL2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.005); called by muse, mutect2
- DPYSL3 | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 23/34 reads (68%) | called by muse, mutect2, varscan2
- DRAXIN | c.200G>C p.W67S | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DSC2 | c.1109A>C p.D370A | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- DUSP7 | c.419C>T p.T140M | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- EFCAB8 | c.2818G>A p.V940I | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.101); called by muse, mutect2
- EPHA2 | c.964T>C p.S322P | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2
- F13A1 | c.1676C>T p.T559I | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- FRYL | c.1204A>G p.T402A | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GNPAT | c.1288C>A p.P430T | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- H3C12 | c.295G>C p.A99P | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); called by muse, mutect2
- HDAC5 | c.2842A>T p.I948F | Missense Mutation (SNP) | VAF 48/98 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- HK1 | c.1265A>G p.Q422R | Missense Mutation (SNP) | VAF 53/99 reads (54%) | SIFT tolerated (0.88); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- HLA-DPB1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 59/171 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- HYKK | c.1047T>A p.F349L | Missense Mutation (SNP) | VAF 23/284 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- IGHV2-70D | c.347G>A p.C116Y | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- IGKV4-1 | c.136del p.S46Afs*14 | Frame Shift Del (DEL) | VAF 32/53 reads (60%) | called by pindel, varscan2
- INTS10 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- ITGA10 | c.2057C>T p.S686F | Missense Mutation (SNP) | VAF 12/290 reads (4%) | SIFT tolerated (0.85); PolyPhen benign (0.147); called by muse, mutect2
- KBTBD3 | c.1516C>A p.P506T | Missense Mutation (SNP) | VAF 67/174 reads (39%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- KLHDC7B | c.1573C>T p.P525S (on ENST00000395676; = p.P1166S on NM_138433.5) | Missense Mutation (SNP) | VAF 65/128 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- LRIF1 | c.338A>G p.D113G | Missense Mutation (SNP) | VAF 118/215 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- LRP2 | c.8088T>A p.N2696K | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- LRTOMT | c.125del p.K42Sfs*9 | Frame Shift Del (DEL) | VAF 9/35 reads (26%) | called by mutect2, pindel, varscan2
- LRWD1 | c.1625T>G p.V542G | Missense Mutation (SNP) | VAF 35/137 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- LSM14A | c.270C>G p.D90E | Missense Mutation (SNP) | VAF 19/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- MACF1 | c.19546G>T p.V6516F (on ENST00000372915; = p.V4561F on NM_012090.5) | Missense Mutation (SNP) | VAF 14/240 reads (6%) | called by muse, mutect2
- MACROD1 | c.930C>A p.D310E | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.333); called by muse, mutect2, varscan2
- MAMDC4 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); called by muse, mutect2
- MCOLN1 | c.842T>C p.I281T | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2
- MYH4 | c.2754A>T p.Q918H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NARF | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 65/147 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NECAP1 | c.167C>G p.A56G | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NOSTRIN | c.1120G>A p.E374K (on ENST00000317647 / NM_001039724.4; = p.E296K on NM_052946.3) | Missense Mutation (SNP) | VAF 18/268 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.401); called by muse, mutect2
- NR2F1 | c.86C>G p.A29G | Missense Mutation (SNP) | VAF 16/142 reads (11%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.005); called by muse, varscan2
- NUP98 | c.3081T>A p.C1027* (on ENST00000359171 / NM_001365126.1; = p.C1010* on NM_016320.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 78/242 reads (32%) | called by muse, mutect2, varscan2
- NYAP1 | c.592del p.R198Gfs*5 | Frame Shift Del (DEL) | VAF 72/264 reads (27%) | called by mutect2, pindel, varscan2
- OR10R2 | c.663T>G p.I221M | Missense Mutation (SNP) | VAF 16/390 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.835); called by muse, mutect2
- OSMR | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 39/151 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PAMR1 | c.683G>C p.G228A | Missense Mutation (SNP) | VAF 24/336 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PAPLN | c.2773C>T p.Q925* (on ENST00000554301; = p.Q898* on NM_173462.4) | Nonsense Mutation (SNP) | VAF 61/114 reads (54%) | called by muse, mutect2, varscan2
- PCDHGA5 | c.1770G>T p.K590N | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PDE4A | c.484T>A p.S162T | Missense Mutation (SNP) | VAF 19/271 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2
- PGAM5 | c.507A>T p.K169N | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.181); called by muse, mutect2, varscan2
- PKHD1 | c.7688G>A p.S2563N | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PKHD1L1 | c.12017G>A p.S4006N | Missense Mutation (SNP) | VAF 59/173 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PLCB1 | c.2486del p.A829Vfs*2 | Frame Shift Del (DEL) | VAF 83/211 reads (39%) | called by mutect2, pindel, varscan2
- POLE | c.1886C>T p.A629V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPIC | c.463_478del p.W155Mfs*11 | Frame Shift Del (DEL) | VAF 30/94 reads (32%) | called by mutect2, pindel, varscan2
- PPM1J | c.336T>A p.N112K | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- PRLH | c.47T>A p.L16Q | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- PRX | c.264G>T p.E88D | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- PTCHD3 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2
- PYDC2 | c.281T>C p.M94T | Missense Mutation (SNP) | VAF 62/348 reads (18%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB11FIP3 | c.835G>A p.V279I | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RABEP2 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 44/89 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- RFX6 | c.121C>G p.P41A | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); called by muse, mutect2
- RGSL1 | c.626A>G p.H209R | Missense Mutation (SNP) | VAF 147/230 reads (64%) | SIFT tolerated (0.74); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- RINL | c.1504dup p.A502Gfs*51 (on ENST00000591812 / NM_001195833.2; = p.A388Gfs*51 on NM_198445.4) | Frame Shift Ins (INS) | VAF 61/119 reads (51%) | called by pindel, varscan2
- RNF217-AS1 | n.384T>G | Splice Region (SNP) | VAF 93/172 reads (54%) | called by muse, mutect2, varscan2
- RPL5 | c.406G>T p.D136Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); called by muse, mutect2, varscan2
- SCAMP2 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 7/125 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.094); called by muse, mutect2
- SCN4A | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- SCN5A | c.33C>G p.S11R | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- SDHAF3 | c.107A>G p.K36R | Missense Mutation (SNP) | VAF 26/356 reads (7%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.945); called by muse, mutect2
- SEPTIN8 | c.1311G>T p.Q437H | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- SERPINB1 | c.880C>T p.Q294* | Nonsense Mutation (SNP) | VAF 210/271 reads (77%) | called by muse, mutect2, varscan2
- SETBP1 | c.1891A>T p.K631* | Nonsense Mutation (SNP) | VAF 13/216 reads (6%) | called by muse, mutect2
- SHROOM4 | c.2216C>A p.A739E | Missense Mutation (SNP) | VAF 46/47 reads (98%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SIAH2 | c.257A>C p.Y86S | Missense Mutation (SNP) | VAF 81/208 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- SLC25A44 | c.17A>G p.N6S | Missense Mutation (SNP) | VAF 16/652 reads (2%) | SIFT tolerated (0.38); PolyPhen benign (0.079); called by muse, mutect2
- SLC37A1 | c.959_973del p.F320_K325delins* | Nonsense Mutation (DEL) | VAF 30/106 reads (28%) | called by mutect2, pindel, varscan2
- SORL1 | c.3866G>T p.C1289F | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SRRM4 | c.968A>T p.N323I | Missense Mutation (SNP) | VAF 16/182 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); called by muse, mutect2
- TARDBP | c.940G>T p.G314C | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- TGIF1 | c.611del p.P204Qfs*30 (on ENST00000330513 / NM_001374396.1; = p.P224Qfs*30 on NM_003244.4) | Frame Shift Del (DEL) | VAF 84/320 reads (26%) | called by mutect2, pindel, varscan2
- TIPARP | c.1948G>C p.E650Q | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); called by muse, varscan2
- TMCC2 | c.2084G>A p.W695* | Nonsense Mutation (SNP) | VAF 13/241 reads (5%) | called by muse, mutect2
- TMEM237 | c.1186G>T p.E396* (on ENST00000409883 / NM_001044385.3; = p.E388* on NM_152388.4) | Nonsense Mutation (SNP) | VAF 15/316 reads (5%) | called by muse, mutect2
- TNS1 | c.4106C>T p.S1369F | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TOR1B | c.641+1G>T p.X214_splice | Splice Site (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- TP53 | c.894_910del p.E298Dfs*2 | Frame Shift Del (DEL) | VAF 50/184 reads (27%) | called by pindel, varscan2
- TRMT11 | c.113C>A p.A38D | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSC22D1 | c.3055C>G p.Q1019E (on ENST00000458659 / NM_183422.4; = p.Q90E on NM_006022.4) | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TSPAN19 | c.296T>C p.V99A | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TTN | c.49679A>T p.Y16560F (on ENST00000591111; = p.Y9136F on NM_003319.4) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | PolyPhen probably damaging (0.994); called by muse, mutect2
- TYW1 | c.499del p.T167Lfs*3 | Frame Shift Del (DEL) | VAF 110/276 reads (40%) | called by mutect2, pindel, varscan2
- UBXN10 | c.752T>A p.F251Y | Missense Mutation (SNP) | VAF 77/252 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- USP43 | c.190G>C p.A64P | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VAC14 | c.1454G>A p.G485D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- WDR97 | c.1172C>G p.P391R | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2
- XPOT | c.1168A>G p.N390D | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.4); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ZAP70 | c.1329C>A p.H443Q | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB16 | c.575G>T p.G192V | Missense Mutation (SNP) | VAF 68/252 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ZBTB21 | c.3000_3001delinsT p.E1000Dfs*97 | Frame Shift Del (DEL) | VAF 33/163 reads (20%) | called by pindel, varscan2*
- ZBTB26 | c.1275A>T p.K425N | Missense Mutation (SNP) | VAF 52/175 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ZC3H12D | c.802T>A p.Y268N | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZFHX4 | c.355T>A p.L119I | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.225); called by muse, mutect2
- ZNF3 | c.862G>A p.E288K | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- ZNF415 | c.688C>G p.H230D | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ZNF605 | c.1235A>G p.Q412R | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ZNF611 | c.1570A>T p.S524C | Missense Mutation (SNP) | VAF 63/247 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF727 | c.505A>T p.R169* | Nonsense Mutation (SNP) | VAF 98/219 reads (45%) | called by muse, mutect2, varscan2
- ZNF880 | c.632C>G p.P211R | Missense Mutation (SNP) | VAF 59/158 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- ZSCAN22 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSCAN32 | c.10G>T p.V4L (on ENST00000396846; = p.V5L on NM_001284527.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/245 reads (48%) | SIFT tolerated, low confidence (0.33); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- ADAM29 | c.1143G>A p.R381= | Silent (SNP) | VAF 54/163 reads (33%) | called by muse, mutect2, varscan2
- AHCTF1 | c.2196T>G p.P732= (on ENST00000366508; = p.P706= on NM_015446.5) | Silent (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- ALG2 | c.420A>T p.P140= | Silent (SNP) | VAF 43/148 reads (29%) | called by muse, mutect2, varscan2
- ANKRD27 | c.2352C>T p.A784= | Silent (SNP) | VAF 9/18 reads (50%) | called by muse, mutect2, varscan2
- AQR | c.4248C>T p.D1416= | Silent (SNP) | VAF 105/508 reads (21%) | called by muse, mutect2, varscan2
- ARHGAP39 | c.1056G>A p.K352= | Silent (SNP) | VAF 19/278 reads (7%) | catalogued as COSV52770623; called by muse, mutect2
- ATF3 | c.330G>A p.K110= | Silent (SNP) | VAF 16/81 reads (20%) | called by muse, mutect2, varscan2
- CCNK | c.1374C>T p.Y458= | Silent (SNP) | VAF 38/67 reads (57%) | catalogued as rs757619350; called by muse, mutect2, varscan2
- CHD5 | c.4506C>A p.T1502= | Silent (SNP) | VAF 40/115 reads (35%) | catalogued as COSV99312138; called by muse, mutect2, varscan2
- CHRM4 | c.351C>T p.N117= | Silent (SNP) | VAF 86/258 reads (33%) | catalogued as rs200711711, COSV63126667; called by muse, mutect2, varscan2
- COG7 | c.966C>T p.A322= | Silent (SNP) | VAF 4/87 reads (5%) | called by muse, mutect2
- COL9A1 | c.2106G>A p.K702= | Silent (SNP) | VAF 28/47 reads (60%) | catalogued as rs774146890, COSV57891804; ClinVar: likely benign; called by muse, mutect2, varscan2
- CYFIP1 | c.2490C>T p.H830= | Silent (SNP) | VAF 20/283 reads (7%) | called by muse, mutect2
- DIP2C | c.2523G>T p.V841= | Silent (SNP) | VAF 98/286 reads (34%) | catalogued as rs573371081; called by muse, mutect2, varscan2
- DNAH6 | c.3304C>T p.L1102= | Silent (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- ECPAS | c.2424C>T p.C808= | Silent (SNP) | VAF 79/227 reads (35%) | called by muse, mutect2, varscan2
- EPB42 | c.1227C>A p.S409= (on ENST00000441366 / NM_001114134.2; = p.S439= on NM_000119.3) | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- ESPL1 | c.3639C>T p.S1213= | Silent (SNP) | VAF 105/225 reads (47%) | catalogued as rs753840797; called by muse, mutect2, varscan2
- FBXL17 | c.732C>T p.D244= | Silent (SNP) | VAF 10/19 reads (53%) | called by muse, mutect2, varscan2
- FCRLB | c.1185A>G p.P395= | Silent (SNP) | VAF 137/446 reads (31%) | called by muse, mutect2, varscan2
- FUBP3 | c.1518G>A p.Q506= | Silent (SNP) | VAF 12/55 reads (22%) | called by muse, mutect2
- GEMIN4 | c.1875A>G p.L625= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as rs1283667429; called by muse, mutect2, varscan2
- GEMIN4 | c.333C>A p.I111= | Silent (SNP) | VAF 97/233 reads (42%) | called by muse, mutect2, varscan2
- GGT6 | c.732C>T p.G244= (on ENST00000574154 / NM_001122890.3; = p.G212= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 53/114 reads (46%) | catalogued as rs373381271, COSV54593697; called by muse, mutect2, varscan2
- HDAC2 | c.444A>T p.A148= | Silent (SNP) | VAF 16/212 reads (8%) | called by muse, mutect2
- HEY1 | c.580C>T p.L194= | Silent (SNP) | VAF 51/183 reads (28%) | called by muse, mutect2, varscan2
- HP | c.1068C>T p.G356= | Silent (SNP) | VAF 61/125 reads (49%) | catalogued as rs774808400; called by muse, mutect2, varscan2
- IGHV3-23 | c.24T>C p.L8= | Silent (SNP) | VAF 22/122 reads (18%) | catalogued as rs566916785; called by muse, varscan2
- IGKV4-1 | c.177A>G p.L59= | Silent (SNP) | VAF 50/52 reads (96%) | catalogued as rs551368026; called by muse, varscan2
- IRS1 | c.900C>A p.T300= | Silent (SNP) | VAF 17/194 reads (9%) | called by muse, mutect2
- ITPRIP | c.1452G>T p.V484= | Silent (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- KISS1 | c.237G>T p.G79= | Silent (SNP) | VAF 21/93 reads (23%) | called by muse, mutect2, varscan2
- KMT5A | c.981G>A p.A327= | Silent (SNP) | VAF 57/127 reads (45%) | catalogued as rs199916420; called by muse, mutect2, varscan2
- KPRP | c.633G>A p.R211= | Silent (SNP) | VAF 36/728 reads (5%) | called by muse, mutect2
- LRP1 | c.7413C>T p.A2471= | Silent (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- LUC7L | c.171A>T p.G57= | Silent (SNP) | VAF 33/415 reads (8%) | called by muse, mutect2
- MR1 | c.633A>G p.K211= | Silent (SNP) | VAF 64/205 reads (31%) | called by muse, mutect2, varscan2
- MTMR11 | c.537G>A p.L179= (on ENST00000439741 / NM_001145862.2; = p.L107= on NM_181873.3) | Silent (SNP) | VAF 26/264 reads (10%) | catalogued as COSV100808949; called by muse, mutect2
- NCMAP | c.120C>A p.V40= | Silent (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2, varscan2
- NEK8 | c.1365G>A p.V455= | Silent (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- NSMCE1 | c.744G>A p.E248= | Silent (SNP) | VAF 65/129 reads (50%) | called by muse, mutect2, varscan2
- PCDH12 | c.2574C>G p.A858= | Silent (SNP) | VAF 11/159 reads (7%) | called by muse, mutect2
- PCDHA8 | c.1629G>A p.P543= | Silent (SNP) | VAF 18/39 reads (46%) | catalogued as rs555722520, COSV65333069, COSV65333143; called by muse, mutect2, varscan2
- PEX1 | c.2358A>T p.V786= | Silent (SNP) | VAF 16/259 reads (6%) | called by muse, mutect2
- PEX11B | c.615C>G p.P205= | Silent (SNP) | VAF 14/232 reads (6%) | called by muse, mutect2
- PHACTR4 | c.1398C>A p.P466= (on ENST00000373839 / NM_001350159.2; = p.P476= on NM_023923.4) | Silent (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- PHLDB1 | c.2832C>T p.H944= | Silent (SNP) | VAF 21/81 reads (26%) | called by muse, mutect2, varscan2
- PSG8 | c.324G>A p.L108= | Silent (SNP) | VAF 101/258 reads (39%) | catalogued as COSV100126544; called by muse, mutect2, varscan2
- PTCHD4 | c.729G>C p.L243= | Silent (SNP) | VAF 62/197 reads (31%) | called by muse, mutect2, varscan2
- PTHLH | c.384C>T p.G128= | Silent (SNP) | VAF 10/240 reads (4%) | catalogued as COSV52368913; called by muse, mutect2
- PTK2 | c.2406G>C p.V802= | Silent (SNP) | VAF 13/321 reads (4%) | called by muse, mutect2
- PTPN21 | c.2256C>T p.A752= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV100161522; called by muse, mutect2, varscan2
- RIMBP2 | c.2748A>T p.A916= | Silent (SNP) | VAF 42/100 reads (42%) | called by muse, mutect2, varscan2
- RXFP3 | c.102G>T p.A34= | Silent (SNP) | VAF 51/245 reads (21%) | called by muse, mutect2, varscan2
- SALL1 | c.3618A>T p.L1206= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- SLC16A14 | c.1407A>G p.K469= | Silent (SNP) | VAF 28/68 reads (41%) | called by muse, mutect2, varscan2
- SORBS3 | c.1323G>A p.E441= | Silent (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2, varscan2
- SYNE3 | c.2640C>T p.Y880= | Silent (SNP) | VAF 35/221 reads (16%) | called by muse, mutect2, varscan2
- TBK1 | c.900A>T p.A300= | Silent (SNP) | VAF 7/123 reads (6%) | called by muse, mutect2
- TGFBRAP1 | c.831A>G p.Q277= | Silent (SNP) | VAF 9/211 reads (4%) | called by muse, mutect2
- UXS1 | c.585C>T p.A195= | Silent (SNP) | VAF 17/77 reads (22%) | called by muse, mutect2, varscan2
- ZC3H13 | c.3723G>T p.L1241= | Silent (SNP) | VAF 76/76 reads (100%) | called by muse, mutect2, varscan2
- ZNF577 | c.636G>A p.K212= | Silent (SNP) | VAF 20/176 reads (11%) | called by muse, mutect2, varscan2
- AADACL3 | c.*657G>A | 3'UTR (SNP) | VAF 6/118 reads (5%) | catalogued as rs1046379808; called by muse, mutect2
- AC108734.4 | n.1765G>T | RNA (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- ACOT8 | c.262+1341C>A | Intron (SNP) | VAF 29/59 reads (49%) | called by muse, mutect2, varscan2
- ADAM28 | c.1567+420C>T | Intron (SNP) | VAF 4/21 reads (19%) | called by mutect2, varscan2
- ADAMTSL1 | c.5182+103T>A | Intron (SNP) | VAF 8/218 reads (4%) | called by muse, mutect2
- ADCY5 | c.2930+340G>A | Intron (SNP) | VAF 7/81 reads (9%) | called by muse, mutect2
- ADGRD2 | c.69-61G>A | Intron (SNP) | VAF 13/30 reads (43%) | called by muse, mutect2, varscan2
- ADRA2B | c.*1366T>A | 3'UTR (SNP) | VAF 12/350 reads (3%) | called by muse, mutect2
- AHSA2P | n.1510C>T | RNA (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- AIF1L | c.*2453C>T | 3'UTR (SNP) | VAF 34/104 reads (33%) | called by muse, mutect2, varscan2
- ALG10B | c.172-97C>T | Intron (SNP) | VAF 38/145 reads (26%) | called by muse, mutect2, varscan2
- AMD1 | c.*1004G>C | 3'UTR (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- ANKRD31 | c.104+32C>A | Intron (SNP) | VAF 28/43 reads (65%) | called by muse, mutect2, varscan2
- AREL1 | c.482-1543C>T | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as rs550438409; called by mutect2, varscan2
- ARHGEF25 | c.-337G>T | 5'UTR (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- ARHGEF5 | c.*460C>T | 3'UTR (SNP) | VAF 39/142 reads (27%) | called by muse, mutect2, varscan2
- ASCL4 | c.-411T>A | 5'UTR (SNP) | VAF 8/92 reads (9%) | called by muse, mutect2
- ATP13A5 | c.2159-21C>A | Intron (SNP) | VAF 22/100 reads (22%) | called by muse, mutect2, varscan2
- B2M | c.*351G>C | 3'UTR (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- B3GALT6 | c.*1017C>A | 3'UTR (SNP) | VAF 86/275 reads (31%) | called by muse, mutect2, varscan2
- BCAP29 | c.344+102G>A | Intron (SNP) | VAF 9/23 reads (39%) | called by muse, mutect2, varscan2
- BCL2 | c.*2491A>G | 3'UTR (SNP) | VAF 20/63 reads (32%) | catalogued as rs1009407487; called by muse, mutect2, varscan2
- BRCA1 | c.135-4013G>C | Intron (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- BTN3A2 | c.*1818A>C | 3'UTR (SNP) | VAF 14/235 reads (6%) | called by muse, mutect2
- C10orf90 | c.*427G>A | 3'UTR (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- C22orf39 | c.*2944G>A | 3'UTR (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- C2orf91 | n.2245A>G | RNA (SNP) | VAF 50/145 reads (34%) | called by muse, mutect2, varscan2
- C7 | c.*547C>A | 3'UTR (SNP) | VAF 9/51 reads (18%) | called by muse, mutect2, varscan2
- CACNA1E | c.*8986C>T | 3'UTR (SNP) | VAF 6/64 reads (9%) | called by muse, mutect2
- CBX8 | c.*603C>T | 3'UTR (SNP) | VAF 15/51 reads (29%) | called by muse, mutect2, varscan2
- CCDC38 | c.37+1533C>T | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1019372914; called by muse, mutect2
- CCNT2 | c.774+138C>T | Intron (SNP) | VAF 61/116 reads (53%) | called by muse, mutect2, varscan2
- CD1D | chr1:158177012 T>A | 5'Flank (SNP) | VAF 23/69 reads (33%) | called by muse, mutect2, varscan2
- CDIPT | chr16:29865194 G>C | 5'Flank (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CEACAM19 | c.576-98C>A | Intron (SNP) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- CEACAM19 | c.576-97C>A | Intron (SNP) | VAF 5/25 reads (20%) | called by mutect2, varscan2
- CHAF1B | c.*215C>T | 3'UTR (SNP) | VAF 44/74 reads (59%) | catalogued as rs571857716; called by muse, mutect2, varscan2
- CLDN18 | c.*1601C>T | 3'UTR (SNP) | VAF 18/54 reads (33%) | catalogued as rs1002704017; called by muse, mutect2, varscan2
- CLEC5A | c.*1271G>A | 3'UTR (SNP) | VAF 9/83 reads (11%) | called by muse, mutect2, varscan2
- COL24A1 | c.*917G>C | 3'UTR (SNP) | VAF 38/79 reads (48%) | catalogued as rs1490456958; called by muse, mutect2, varscan2
- CPED1 | c.*190C>T | 3'UTR (SNP) | VAF 19/58 reads (33%) | called by muse, mutect2, varscan2
- CYFIP2 | chr5:157394442 G>A | 3'Flank (SNP) | VAF 48/120 reads (40%) | called by muse, mutect2, varscan2
- CYP2B7P | n.896G>T | RNA (SNP) | VAF 25/136 reads (18%) | called by muse, mutect2, varscan2
- DBF4B | c.1190-603G>A | Intron (SNP) | VAF 51/117 reads (44%) | called by muse, mutect2, varscan2
- DDX10 | c.2450+847A>G | Intron (SNP) | VAF 15/80 reads (19%) | called by muse, mutect2, varscan2
- DDX19B | c.107-48del | Intron (DEL) | VAF 87/197 reads (44%) | called by mutect2, pindel, varscan2
- DEFB132 | c.*1387G>C | 3'UTR (SNP) | VAF 46/86 reads (53%) | called by muse, mutect2, varscan2
- DENND10 | c.*385G>C | 3'UTR (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- DFFB | c.*1260A>G | 3'UTR (SNP) | VAF 44/135 reads (33%) | called by muse, mutect2, varscan2
- DLAT | c.*1123T>G | 3'UTR (SNP) | VAF 84/165 reads (51%) | called by muse, mutect2, varscan2
- DMTF1 | chr7:87152314 G>C | 5'Flank (SNP) | VAF 73/214 reads (34%) | called by muse, mutect2, varscan2
- DPYSL3 | c.-95C>A | 5'UTR (SNP) | VAF 14/43 reads (33%) | called by muse, mutect2, varscan2
- DUSP7 | c.952+1339G>C | Intron (SNP) | VAF 35/119 reads (29%) | called by muse, mutect2, varscan2
- ELP1 | c.650-43A>T | Intron (SNP) | VAF 34/53 reads (64%) | called by muse, mutect2, varscan2
- EMX2 | c.*370G>T | 3'UTR (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- ENPEP | c.*1117T>A | 3'UTR (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2, varscan2
- FAM189A1 | c.*125C>T | 3'UTR (SNP) | VAF 42/211 reads (20%) | called by muse, mutect2, varscan2
- FAM53C | c.*350T>G | 3'UTR (SNP) | VAF 60/146 reads (41%) | called by muse, mutect2, varscan2
- FAM78A | c.*2494G>T | 3'UTR (SNP) | VAF 17/131 reads (13%) | called by muse, mutect2, varscan2
- FAM98B | c.*1266_*1278del | 3'UTR (DEL) | VAF 16/118 reads (14%) | called by mutect2, pindel
- FBXL21P | n.1119A>G | RNA (SNP) | VAF 41/97 reads (42%) | called by muse, mutect2, varscan2
- FCER1G | c.*43C>T | 3'UTR (SNP) | VAF 88/412 reads (21%) | called by muse, mutect2, varscan2
- FCGR3A | c.*119G>A | 3'UTR (SNP) | VAF 23/772 reads (3%) | called by muse, mutect2
- FKBP7 | c.*1845dup | 3'UTR (INS) | VAF 36/66 reads (55%) | called by mutect2, varscan2
- FOXC2 | c.*237G>A | 3'UTR (SNP) | VAF 7/10 reads (70%) | called by muse, mutect2, varscan2
- FOXL2NB | c.*954C>T | 3'UTR (SNP) | VAF 38/167 reads (23%) | called by muse, mutect2, varscan2
- FOXRED1 | c.*173C>A | 3'UTR (SNP) | VAF 49/174 reads (28%) | catalogued as rs1478624812; called by muse, mutect2, varscan2
- FTO | c.*1800G>A | 3'UTR (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2, varscan2
- FUT4 | c.*417G>A | 3'UTR (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- FYB1 | c.*1724G>T | 3'UTR (SNP) | VAF 9/55 reads (16%) | catalogued as rs939662187; called by muse, mutect2, varscan2
- FZD5 | c.*2276del | 3'UTR (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- GABARAP | c.-119G>A | 5'UTR (SNP) | VAF 28/58 reads (48%) | catalogued as rs976912366; called by muse, varscan2
- GASK1A | c.-130C>T | 5'UTR (SNP) | VAF 52/93 reads (56%) | called by muse, mutect2, varscan2
- GCKR | c.969-44T>C | Intron (SNP) | VAF 22/246 reads (9%) | called by muse, mutect2
- GFOD1 | c.*6804C>T | 3'UTR (SNP) | VAF 64/233 reads (27%) | called by muse, mutect2, varscan2
- GLB1L3 | c.812-70G>T | Intron (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2
- GORAB | c.662+85C>T | Intron (SNP) | VAF 18/274 reads (7%) | called by muse, mutect2
- GPX2 | chr14:64944476 G>A | 5'Flank (SNP) | VAF 29/50 reads (58%) | called by muse, mutect2, varscan2
- GTDC1 | c.180-147C>A | Intron (SNP) | VAF 6/10 reads (60%) | called by muse, mutect2, varscan2
- GUCY1A1 | c.*1797C>A | 3'UTR (SNP) | VAF 29/75 reads (39%) | called by muse, mutect2, varscan2
- GUF1 | c.*374C>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- GULP1 | c.399+50G>T | Intron (SNP) | VAF 28/69 reads (41%) | called by muse, mutect2, varscan2
- HAS3 | c.*2398C>G | 3'UTR (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- HGSNAT | c.*3211C>A | 3'UTR (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- HGSNAT | c.*3212C>A | 3'UTR (SNP) | VAF 22/76 reads (29%) | called by muse, mutect2, varscan2
- HMGCLL1 | c.*657T>A | 3'UTR (SNP) | VAF 27/97 reads (28%) | catalogued as rs929250304; called by muse, mutect2, varscan2
- HS6ST2 | c.*1058A>C | 3'UTR (SNP) | VAF 4/33 reads (12%) | called by mutect2, varscan2
- HSBP1L1 | c.118+154A>C | Intron (SNP) | VAF 12/23 reads (52%) | called by muse, mutect2
- HSPA12A | c.*2953G>A | 3'UTR (SNP) | VAF 9/103 reads (9%) | called by muse, mutect2
- HSPA12A | c.*2684A>T | 3'UTR (SNP) | VAF 30/113 reads (27%) | called by muse, mutect2, varscan2
- IFIT5 | c.*1184T>A | 3'UTR (SNP) | VAF 37/66 reads (56%) | called by muse, mutect2, varscan2
- IGHV3-23 | c.-75C>T | 5'UTR (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2, varscan2
- IQCE | c.*2346G>T | 3'UTR (SNP) | VAF 47/148 reads (32%) | called by muse, mutect2, varscan2
- ITGAL | c.3229-65A>T | Intron (SNP) | VAF 48/124 reads (39%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87701981 C>T | 3'Flank (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- KALRN | c.7193+226T>A | Intron (SNP) | VAF 12/81 reads (15%) | catalogued as rs1345944158; called by muse, mutect2, varscan2
- KANSL1 | c.1289+63A>T | Intron (SNP) | VAF 19/85 reads (22%) | called by muse, mutect2, varscan2
- KBTBD12 | c.*3366G>A | 3'UTR (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- KBTBD4 | c.*128C>T | 3'UTR (SNP) | VAF 26/80 reads (33%) | called by muse, mutect2, varscan2
- KCNQ2 | c.1247+150C>T | Intron (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- KCTD13 | c.*243C>T | 3'UTR (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- KLHDC7B | c.*435G>C | 3'UTR (SNP) | VAF 11/133 reads (8%) | called by muse, mutect2
- KLRB1 | c.*50T>C | 3'UTR (SNP) | VAF 10/210 reads (5%) | catalogued as COSV99987208; called by muse, mutect2
- LACRT | c.*6T>A | 3'UTR (SNP) | VAF 16/277 reads (6%) | called by muse, mutect2
- LINC02412 | n.1277T>A | RNA (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- LPIN2 | c.*1607A>T | 3'UTR (SNP) | VAF 27/98 reads (28%) | called by muse, mutect2, varscan2
- LRATD1 | c.*4804T>A | 3'UTR (SNP) | VAF 14/107 reads (13%) | called by muse, mutect2, varscan2
- LRRC15 | c.*1873_*1879del | 3'UTR (DEL) | VAF 53/161 reads (33%) | called by mutect2, pindel, varscan2
- LUZP2 | c.*3058A>T | 3'UTR (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- LY6G5C | c.346-885C>T | Intron (SNP) | VAF 85/258 reads (33%) | called by muse, mutect2, varscan2
- MACC1 | chr7:20139144 G>C | 3'Flank (SNP) | VAF 50/166 reads (30%) | called by muse, mutect2, varscan2
- MAGEA5 | n.333G>A | RNA (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- MAN2B2 | c.*374T>G | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- MAP4 | c.1999+4309A>G | Intron (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- MATR3 | c.-157_-155del | 5'UTR (DEL) | VAF 17/48 reads (35%) | called by mutect2, pindel, varscan2
- MAU2 | c.*137C>G | 3'UTR (SNP) | VAF 112/356 reads (31%) | called by muse, mutect2, varscan2
- MFN2 | c.709-42C>A | Intron (SNP) | VAF 92/285 reads (32%) | catalogued as rs1181707568; called by muse, varscan2
- MGLL | c.*1541A>T | 3'UTR (SNP) | VAF 9/150 reads (6%) | called by muse, mutect2
- MTBP | chr8:120445371 T>G | 5'Flank (SNP) | VAF 21/75 reads (28%) | called by muse, mutect2, varscan2
- MTRF1L | c.*2484del | 3'UTR (DEL) | VAF 94/275 reads (34%) | called by mutect2, pindel, varscan2
- MVB12B | c.*2383G>T | 3'UTR (SNP) | VAF 44/73 reads (60%) | called by muse, mutect2, varscan2
- MYO16 | c.*936G>A | 3'UTR (SNP) | VAF 7/111 reads (6%) | catalogued as rs1424079552; called by muse, mutect2
- MYO3A | c.732-599C>T | Intron (SNP) | VAF 33/137 reads (24%) | called by muse, mutect2, varscan2
- MYO5C | c.4043-170C>T | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
- NDST1 | c.*3186C>T | 3'UTR (SNP) | VAF 26/48 reads (54%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-745C>T | Intron (SNP) | VAF 12/163 reads (7%) | called by muse, mutect2
- NR6A1 | c.*410T>G | 3'UTR (SNP) | VAF 7/104 reads (7%) | called by muse, mutect2
- NSD2 | c.2014-52G>A | Intron (SNP) | VAF 36/92 reads (39%) | called by muse, mutect2, varscan2
- NSF | c.*747A>T | 3'UTR (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2, varscan2
- NT5DC2 | c.121+126C>G | Intron (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- NT5DC2 | c.121+125C>A | Intron (SNP) | VAF 4/23 reads (17%) | catalogued as rs1219786417; called by muse, mutect2, varscan2
- OGA | c.1984+644del | Intron (DEL) | VAF 10/63 reads (16%) | catalogued as rs202057076; called by pindel, varscan2
- ONECUT2 | c.*11750dup | 3'UTR (INS) | VAF 18/60 reads (30%) | called by mutect2, varscan2
- OR7E24 | c.*5G>T | 3'UTR (SNP) | VAF 55/249 reads (22%) | called by muse, mutect2, varscan2
- PAK1IP1 | c.-7C>G | 5'UTR (SNP) | VAF 53/252 reads (21%) | called by muse, mutect2, varscan2
- PAPOLB | c.*1233A>G | 3'UTR (SNP) | VAF 47/117 reads (40%) | called by muse, mutect2, varscan2
- PAQR6 | c.760+39G>A | Intron (SNP) | VAF 53/187 reads (28%) | called by muse, mutect2, varscan2
- PARP8 | c.*400T>A | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- PDE4D | c.456-59882C>A | Intron (SNP) | VAF 53/103 reads (51%) | called by muse, mutect2, varscan2
- PDIA4 | c.*590G>A | 3'UTR (SNP) | VAF 60/174 reads (34%) | called by muse, mutect2, varscan2
- PDZRN4 | c.*106_*109del | 3'UTR (DEL) | VAF 59/189 reads (31%) | called by mutect2, pindel, varscan2
- PEG10 | c.*4798G>T | 3'UTR (SNP) | VAF 29/95 reads (31%) | called by muse, mutect2, varscan2
- PIK3R3 | c.*3382T>C | 3'UTR (SNP) | VAF 30/57 reads (53%) | called by muse, mutect2, varscan2
- PKNOX2 | c.*66G>A | 3'UTR (SNP) | VAF 35/106 reads (33%) | catalogued as rs879203288, COSV100021397; called by muse, mutect2, varscan2
- PLCD3 | c.1712-58G>C | Intron (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- PLOD2 | c.*89G>A | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- POU2AF1 | c.*1248C>T | 3'UTR (SNP) | VAF 8/58 reads (14%) | catalogued as rs376428762; called by muse, varscan2
- PPM1L | c.*589C>G | 3'UTR (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- PPP1R9A | c.*2792A>G | 3'UTR (SNP) | VAF 11/39 reads (28%) | catalogued as rs964246763; called by muse, mutect2, varscan2
- PRKD1 | c.*714T>C | 3'UTR (SNP) | VAF 21/31 reads (68%) | called by muse, mutect2, varscan2
- PRKRIP1 | c.*1307C>G | 3'UTR (SNP) | VAF 14/219 reads (6%) | called by muse, mutect2
- PSMG4 | c.251-1210T>C | Intron (SNP) | VAF 64/227 reads (28%) | called by muse, mutect2, varscan2
- PTEN | c.*3989G>T | 3'UTR (SNP) | VAF 33/71 reads (46%) | called by muse, mutect2, varscan2
- PTGR1 | c.209+194C>A | Intron (SNP) | VAF 80/297 reads (27%) | called by muse, mutect2, varscan2
- PXDN | c.1947-110del | Intron (DEL) | VAF 14/34 reads (41%) | called by mutect2, pindel, varscan2
- RAB40C | c.*1402G>A | 3'UTR (SNP) | VAF 8/117 reads (7%) | called by muse, mutect2
- RBM24 | c.169-435G>T | Intron (SNP) | VAF 37/140 reads (26%) | called by muse, mutect2, varscan2
- RET | c.3187+484C>T | Intron (SNP) | VAF 6/77 reads (8%) | catalogued as rs1564502216; called by muse, mutect2
- RPL23 | c.*15+891G>T | Intron (SNP) | VAF 4/69 reads (6%) | called by muse, mutect2
- RPS27 | c.116-44_116-43dup | Intron (INS) | VAF 30/125 reads (24%) | called by mutect2, pindel, varscan2
- RRAGB | chrX:55758634 T>G | 3'Flank (SNP) | VAF 4/36 reads (11%) | called by muse, mutect2, varscan2
- RRM2B | c.*1033del | 3'UTR (DEL) | VAF 30/110 reads (27%) | called by mutect2, pindel, varscan2
- RRM2B | c.*67A>C | 3'UTR (SNP) | VAF 11/356 reads (3%) | catalogued as COSV52569016; called by muse, mutect2
- RTN3 | c.*532T>C | 3'UTR (SNP) | VAF 22/264 reads (8%) | called by muse, mutect2
- RUFY3 | c.*1295T>G | 3'UTR (SNP) | VAF 15/34 reads (44%) | catalogued as rs961617856; called by muse, mutect2, varscan2
- SAR1B | c.*5500G>A | 3'UTR (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-36158C>T | Intron (SNP) | VAF 15/119 reads (13%) | catalogued as rs867142740; called by muse, mutect2, varscan2
- SESN3 | c.*5181A>G | 3'UTR (SNP) | VAF 40/90 reads (44%) | called by muse, mutect2, varscan2
- SEZ6L | c.*1346C>G | 3'UTR (SNP) | VAF 6/122 reads (5%) | called by muse, mutect2
- SGK1 | c.-266C>A | 5'UTR (SNP) | VAF 65/137 reads (47%) | called by muse, mutect2, varscan2
- SH3TC1 | c.173-38T>G | Intron (SNP) | VAF 13/182 reads (7%) | catalogued as rs1411205587; called by muse, mutect2
- SKP1 | c.457-241G>A | Intron (SNP) | VAF 90/209 reads (43%) | called by muse, mutect2, varscan2
- SLC30A7 | c.-2_1del | 5'UTR (DEL) | VAF 79/170 reads (46%) | catalogued as rs976431646; called by pindel, varscan2
- SLC44A1 | c.*5794C>T | 3'UTR (SNP) | VAF 60/185 reads (32%) | catalogued as rs886283955; called by muse, mutect2, varscan2
- SLC5A12 | c.1153+726T>G | Intron (SNP) | VAF 49/78 reads (63%) | called by muse, mutect2, varscan2
- SLC9A7P1 | n.1234T>G | RNA (SNP) | VAF 19/113 reads (17%) | called by muse, mutect2, varscan2
- SMAD9 | c.*2054C>T | 3'UTR (SNP) | VAF 27/28 reads (96%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*28G>A | 3'UTR (SNP) | VAF 58/168 reads (35%) | catalogued as rs1255919349; called by muse, varscan2
- SMTN | c.-80-207C>T | Intron (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- SMU1 | c.-34G>C | 5'UTR (SNP) | VAF 150/450 reads (33%) | called by muse, varscan2
- SMUG1 | c.285+507G>C | Intron (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- SNX15 | c.*642G>T | 3'UTR (SNP) | VAF 16/53 reads (30%) | called by muse, mutect2, varscan2
- SNX20 | chr16:50667419 C>A | 3'Flank (SNP) | VAF 87/179 reads (49%) | called by muse, mutect2, varscan2
- SOX2 | c.-33C>T | 5'UTR (SNP) | VAF 13/32 reads (41%) | called by muse, mutect2, varscan2
- SP7 | c.*937C>T | 3'UTR (SNP) | VAF 47/97 reads (48%) | called by muse, mutect2, varscan2
- SPATA8 | n.259C>A | RNA (SNP) | VAF 20/76 reads (26%) | called by muse, mutect2, varscan2
- SPICE1 | c.*1336G>T | 3'UTR (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- SPOP | c.*1349G>T | 3'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- SPX | c.*128C>T | 3'UTR (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- SRPRA | c.365+14C>G | Intron (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- STEAP4 | c.*8475A>T | 3'UTR (SNP) | VAF 9/242 reads (4%) | called by muse, mutect2
- SYT10 | c.*124G>A | 3'UTR (SNP) | VAF 28/89 reads (31%) | called by muse, mutect2, varscan2
- SYTL2 | c.1562-169C>A | Intron (SNP) | VAF 40/478 reads (8%) | called by muse, mutect2
- TAS2R9 | c.-87G>C | 5'UTR (SNP) | VAF 33/65 reads (51%) | called by muse, mutect2, varscan2
- TFEC | c.*656A>C | 3'UTR (SNP) | VAF 35/106 reads (33%) | called by muse, mutect2, varscan2
- THRA | c.1111-1257G>A | Intron (SNP) | VAF 9/86 reads (10%) | called by muse, mutect2, varscan2
- THY1 | c.*1002C>T | 3'UTR (SNP) | VAF 13/246 reads (5%) | catalogued as rs1565325603; called by muse, mutect2
- TLN2 | c.-36-9666C>G | Intron (SNP) | VAF 7/86 reads (8%) | called by muse, mutect2
- TMEM109 | c.*222T>G | 3'UTR (SNP) | VAF 88/254 reads (35%) | catalogued as rs1417820397; called by muse, mutect2, varscan2
- TMEM132D | c.-48G>A | 5'UTR (SNP) | VAF 34/66 reads (52%) | called by muse, mutect2, varscan2
- TMEM170B | c.-33del | 5'UTR (DEL) | VAF 16/70 reads (23%) | called by mutect2, pindel, varscan2
- TMPRSS4 | c.43+72A>C | Intron (SNP) | VAF 6/113 reads (5%) | called by muse, mutect2
- TMTC4 | c.778-75G>T | Intron (SNP) | VAF 68/68 reads (100%) | called by muse, mutect2, varscan2
- TPD52L3 | c.*1321G>T | 3'UTR (SNP) | VAF 17/55 reads (31%) | called by muse, mutect2, varscan2
- TPRG1 | c.*1454T>A | 3'UTR (SNP) | VAF 7/117 reads (6%) | called by muse, mutect2
- TRAK1 | c.1963+638G>A | Intron (SNP) | VAF 23/93 reads (25%) | called by muse, mutect2, varscan2
- TRIM24 | c.*162T>C | 3'UTR (SNP) | VAF 21/61 reads (34%) | called by muse, mutect2, varscan2
- TRIM54 | c.-232_-231dup | 5'UTR (INS) | VAF 10/58 reads (17%) | called by mutect2, varscan2
- TRPV3 | c.*1542C>T | 3'UTR (SNP) | VAF 31/68 reads (46%) | called by muse, mutect2
- TRUB1 | c.*119A>T | 3'UTR (SNP) | VAF 10/49 reads (20%) | called by muse, varscan2
- TSC1 | c.*3619G>T | 3'UTR (SNP) | VAF 80/244 reads (33%) | called by muse, mutect2, varscan2
- TTL | c.*2829_*2831delinsAA | 3'UTR (DEL) | VAF 49/165 reads (30%) | called by pindel, varscan2*
- UNC13A | c.*1448G>A | 3'UTR (SNP) | VAF 12/330 reads (4%) | called by muse, mutect2
- UNC45B | c.*1418T>A | 3'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- UQCRH | c.*26C>T | 3'UTR (SNP) | VAF 104/238 reads (44%) | catalogued as rs989359535; called by muse, mutect2, varscan2
- USF3 | c.*5843C>T | 3'UTR (SNP) | VAF 15/57 reads (26%) | catalogued as rs1158333276; called by muse, mutect2, varscan2
- USF3 | c.*5592G>C | 3'UTR (SNP) | VAF 53/150 reads (35%) | catalogued as rs1376797461; called by muse, mutect2, varscan2
- USP2-AS1 | n.1340A>T | RNA (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- UVSSA | c.*7603G>A | 3'UTR (SNP) | VAF 9/20 reads (45%) | called by muse, mutect2
- Unknown | chr7:55707300 G>T | IGR (SNP) | VAF 65/300 reads (22%) | called by muse, mutect2, varscan2
- VGLL3 | c.*3330G>A | 3'UTR (SNP) | VAF 24/62 reads (39%) | called by muse, mutect2, varscan2
- WBP2NL | c.*129G>A | 3'UTR (SNP) | VAF 13/152 reads (9%) | called by muse, mutect2
- XCL1 | c.*624del | 3'UTR (DEL) | VAF 42/137 reads (31%) | called by mutect2, pindel, varscan2
- YARS1 | c.*558C>T | 3'UTR (SNP) | VAF 66/128 reads (52%) | called by muse, mutect2, varscan2
- ZAR1L | c.*57G>C | 3'UTR (SNP) | VAF 7/114 reads (6%) | called by muse, mutect2
- ZNF205 | c.*175A>C | 3'UTR (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- ZNF26 | c.-270G>A | 5'UTR (SNP) | VAF 10/126 reads (8%) | called by muse, mutect2
- ZNF700 | c.*497G>T | 3'UTR (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- ZNF813 | c.*3433T>A | 3'UTR (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- ZNF861P | n.461A>T | RNA (SNP) | VAF 10/161 reads (6%) | called by muse, mutect2
- ZSCAN29 | c.*2276C>T | 3'UTR (SNP) | VAF 41/170 reads (24%) | called by muse, mutect2, varscan2
